Somatic mutation profile of tumor specimen 0DYNNW from CCDI case PBCSWM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 14.4 years (5,248 days).
Specimen 0DYNNW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 126c81a5-ee09-4831-a1a4-1bf234f2e0d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYNMH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cadd472-2c8f-44e5-ab98-866460a58ac9

The open-access MAF lists 36 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, Splice Region 3, Nonsense Mutation 2, Intron 2, 3'UTR 1, 5'UTR 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 156/500 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 470/575 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.6457C>T p.R2153C | Missense Mutation (SNP) | VAF 417/500 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64872312, COSV64880905; called by muse, mutect2, varscan2
- AVPR1B | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 125/325 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as rs782158452, COSV65638107, COSV65638252; called by muse, mutect2, varscan2
- CSMD2 | c.3060C>G p.F1020L | Missense Mutation (SNP) | VAF 54/745 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99587545; called by mutect2, varscan2
- DOT1L | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 112/279 reads (40%) | catalogued as COSV101288721; called by muse, mutect2, varscan2
- HDAC4 | c.1296C>A p.G432= | Splice Region (SNP) | VAF 44/199 reads (22%) | catalogued as COSV61869525; called by muse, mutect2, varscan2
- KCNV2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 96/323 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.131); catalogued as rs746873819; called by muse, mutect2, varscan2
- MGST1 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 78/1054 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs778566629; called by muse, mutect2
- NPR1 | c.3067G>A p.V1023I | Missense Mutation (SNP) | VAF 27/528 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.085); catalogued as COSV64118037; called by muse, mutect2
- OBSL1 | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 57/738 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763498145, COSV54713269; ClinVar: uncertain significance; called by muse, mutect2
- RACGAP1 | c.1252A>G p.I418V | Missense Mutation (SNP) | VAF 38/682 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1263391849; called by muse, mutect2
- RXFP3 | c.1123G>A p.V375M | Missense Mutation (SNP) | VAF 94/364 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs199696955, COSV57507481; called by muse, mutect2, varscan2
- TRIM8 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.099); catalogued as rs777166519; called by muse, mutect2, varscan2
- BZW2 | c.917A>C p.E306A | Missense Mutation (SNP) | VAF 293/784 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CACNA1E | c.2638G>T p.E880* | Nonsense Mutation (SNP) | VAF 111/275 reads (40%) | called by muse, mutect2, varscan2
- CASP2 | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 257/644 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CIC | c.148del p.D50Tfs*155 | Frame Shift Del (DEL) | VAF 150/328 reads (46%) | called by mutect2, varscan2
- CSAD | c.1474G>T p.D492Y (on ENST00000444623 / NM_001244705.2; = p.D519Y on NM_015989.5) | Missense Mutation (SNP) | VAF 35/498 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DMD | c.7342C>T p.P2448S | Missense Mutation (SNP) | VAF 25/580 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- ENPEP | c.2226-8T>A | Splice Region (SNP) | VAF 256/608 reads (42%) | called by mutect2, varscan2
- GAB4 | c.743C>G p.A248G | Missense Mutation (SNP) | VAF 28/708 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.264); called by muse, mutect2
- OR56A5 | c.437G>A p.R146K | Missense Mutation (SNP) | VAF 48/610 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- OR56B1 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 147/522 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- SMARCB1 | c.492G>A p.E164= (on ENST00000263121; = p.E210= on NM_003073.5) | Splice Region (SNP) | VAF 38/376 reads (10%) | called by muse, varscan2
- SOX10 | c.989dup p.H330Qfs*72 | Frame Shift Ins (INS) | VAF 206/395 reads (52%) | called by mutect2, varscan2
- ARL6IP6 | c.159C>T p.R53= | Silent (SNP) | VAF 89/227 reads (39%) | called by muse, mutect2, varscan2
- DACT1 | c.1233G>A p.G411= | Silent (SNP) | VAF 166/350 reads (47%) | called by muse, varscan2
- KIF20B | c.1030T>C p.L344= | Silent (SNP) | VAF 76/876 reads (9%) | catalogued as rs146702249; called by muse, mutect2
- RPTN | c.423C>T p.D141= | Silent (SNP) | VAF 56/959 reads (6%) | catalogued as rs565256584, COSV60167666; called by muse, mutect2
- SCMH1 | c.1176G>A p.V392= (on ENST00000326197 / NM_001031694.2; = p.V345= on NM_012236.4) | Silent (SNP) | VAF 208/582 reads (36%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.1200C>A p.L400= (on ENST00000648592; = p.L366= on NM_182973.2) | Silent (SNP) | VAF 39/420 reads (9%) | called by muse, mutect2
- CHODL | c.79+657T>C | Intron (SNP) | VAF 50/476 reads (11%) | called by muse, mutect2, varscan2
- ERN2 | c.-19G>T | 5'UTR (SNP) | VAF 11/75 reads (15%) | called by muse, mutect2, varscan2
- MS4A3 | c.*89A>T | 3'UTR (SNP) | VAF 16/644 reads (2%) | called by muse, mutect2
- PPIA | c.190-39T>G | Intron (SNP) | VAF 60/131 reads (46%) | called by muse, mutect2, varscan2
